Somatic mutation profile of tumor specimen 0DAWAH from CCDI case PBBJKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,863 days).
Specimen 0DAWAH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69ee434f-3b32-4d88-83ee-917a0064a2fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAWAG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4448f56-0841-4010-a5e7-71d0a68f8ca7

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 4, Silent 4, 3'Flank 2, 5'UTR 2, Intron 2, 5'Flank 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6orf132 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 172/381 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1373685755; called by muse, mutect2, varscan2
- CDC42BPG | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 390/863 reads (45%) | catalogued as rs1036440660; called by muse, mutect2, varscan2
- CELF1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 141/955 reads (15%) | catalogued as COSV60114515; called by muse, mutect2, varscan2
- DCAF8L1 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs749236143, COSV71595229; called by muse, mutect2, varscan2
- KBTBD4 | c.884_886dup p.P295dup | In Frame Ins (INS) | VAF 152/419 reads (36%) | catalogued as COSV58596732, COSV58597734, COSV58597899; called by mutect2, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 323/828 reads (39%) | catalogued as COSV55542953; called by muse, mutect2, varscan2
- OBSCN | c.4106C>T p.T1369M | Missense Mutation (SNP) | VAF 315/1139 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs375911565; called by muse, mutect2, varscan2
- SIPA1L1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 362/414 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1297221334, COSV62168316; called by muse, mutect2, varscan2
- ABCC11 | c.3212C>A p.S1071Y | Missense Mutation (SNP) | VAF 325/520 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ADAMTS13 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 77/1196 reads (6%) | called by muse, mutect2
- ANGPTL6 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 22/872 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- CCDC102B | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 152/1080 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CMTR1 | c.1872G>T p.K624N | Missense Mutation (SNP) | VAF 34/1342 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- MED1 | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 337/827 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- NAPB | c.15del p.K6Rfs*8 | Frame Shift Del (DEL) | VAF 120/297 reads (40%) | called by mutect2, varscan2
- SLC7A11 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 26/999 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); called by muse, mutect2
- TMEM132C | c.3092C>G p.S1031C | Missense Mutation (SNP) | VAF 256/879 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TMPRSS9 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 262/593 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DCHS2 | c.1857G>T p.R619= | Silent (SNP) | VAF 62/798 reads (8%) | catalogued as rs760541474, COSV59720331; called by muse, mutect2
- DIPK1C | c.861C>T p.I287= | Silent (SNP) | VAF 56/726 reads (8%) | called by muse, mutect2
- EPM2AIP1 | c.1428G>A p.K476= | Silent (SNP) | VAF 523/1153 reads (45%) | called by muse, mutect2, varscan2
- MFSD1 | c.1005T>C p.L335= | Silent (SNP) | VAF 145/1009 reads (14%) | called by muse, mutect2, varscan2
- EPHB1 | c.-46C>A | 5'UTR (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- FGFR3P6 | chr1:247123779 G>C | 3'Flank (SNP) | VAF 173/998 reads (17%) | catalogued as rs1188282228; called by muse, mutect2, varscan2
- H4C8 | chr6:26285510 C>T | 5'Flank (SNP) | VAF 382/838 reads (46%) | catalogued as rs755955796; called by muse, mutect2, varscan2
- HDAC6 | c.1994+21C>G | Intron (SNP) | VAF 153/247 reads (62%) | called by muse, mutect2, varscan2
- KCNIP1 | chr5:170735866 C>T | 3'Flank (SNP) | VAF 470/1033 reads (45%) | catalogued as COSV100198732; called by muse, mutect2, varscan2
- RABGAP1 | c.2424+81T>A | Intron (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- RALGPS1 | c.-27C>T | 5'UTR (SNP) | VAF 161/489 reads (33%) | catalogued as rs1164675645; called by muse, mutect2, varscan2
